TCGA case TCGA-RG-A7D4 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Montefiore Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08cbbb39-d05a-48b0-a966-5212c5923c8b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,302 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,098 days (3.0 years); Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 734 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,098 days (3.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Creatinine 1 mg/dL [Blood test normal range lower: 1; Blood test normal range upper: 2].
- Albumin 3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3; Blood test normal range upper: 5].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 1; Blood test normal range upper: 2].
- Platelets 175 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Alpha Fetoprotein 5650 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 9].
- Total Bilirubin 1 mg/dL [Blood test normal range lower: 1; Blood test normal range upper: 2].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection; Viral hepatitis serology tests: Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 172 cm; BMI: 29.4.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RG-A7D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-RG-A7D4-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-RG-A7D4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RG-A7D4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,098 days; disease-specific survival: no event (censored), 1,098 days; disease-free interval: no event (censored), 1,098 days; progression-free interval: no event (censored), 1,098 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RG-A7D4-01A-12D-A33P-01): tumor purity 0.35, ploidy 4.93, whole-genome doublings 2.
